Gene-level copy-number profile of tumor specimen TCGA-06-0138-01A from TCGA case TCGA-06-0138, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 43.1 years (15,736 days).
Specimen TCGA-06-0138-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.9f2ba4ab-d5c0-4b3b-926e-7da611ef1397.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-06-0138-10C (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (2 files).
https://portal.gdc.cancer.gov/files/8066e2a4-db5e-4689-b1b0-c33e4f6a0d31

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 7,171; copy number 2: 49,521; copy number 3: 3,011; copy number 4: 23; copy number 13: 17; copy number 17: 9; copy number 23: 5; copy number 24: 5; copy number 25: 25; copy number 27: 27; copy number 28: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 90 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:54,933,699–55,255,635, 5 genes, copy number 24 (within-gene range 4–24): AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1.
- chr12:57,512,688–57,984,761, 42 genes, copy number 13–25: MIR6758, DDIT3, AC022506.1, MIR616, MBD6, DCTN2, KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2.
- chr12:58,244,378–59,064,238, 7 genes, copy number 17–23 (within-gene range 1–23): RPL21P103, AC025578.1, AC020637.1, LINC02388, LRIG3, AC068305.2, RPS6P22.
- chr12:65,466,820–65,642,372, 2 genes, copy number 28 (within-gene range 1–41): AC025419.1, AC090023.1.
- chr12:68,610,855–68,671,901, 1 gene, copy number 27 (within-gene range 1–27): RAP1B.
- chr12:68,642,519–69,699,476, 33 genes, copy number 17–27 (within-gene range 1–27): ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3.

Autosomal genes at a single copy (total copy number 1): 4,786. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
